Gene-level copy-number profile of tumor specimen TCGA-N5-A4RV-01A from TCGA case TCGA-N5-A4RV, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Uterus, NOS; FIGO stage: Stage IA; Age at diagnosis: 62.9 years (22,978 days).
Specimen TCGA-N5-A4RV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCS.6a58efd3-b8c0-4910-8678-a8fef9e1d55a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-N5-A4RV-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 819 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ec49f0a8-74c6-4021-917c-47f186ccc730

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 45; copy number 2: 9,929; copy number 3: 29,080; copy number 4: 17,882; copy number 5: 1,578; copy number 6: 93; copy number 7: 561; copy number 9: 486; copy number 11: 103; copy number 13: 14; copy number 15: 18; copy number 17: 13.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-N5-A4RV-01A-21D-A28Q-01): tumor purity 0.97, ploidy 3.32, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:110,860,582–110,860,647, 1 gene: MIR297.
- chr22:28,883,572–29,057,488, 1 gene (within-gene range 0–2): ZNRF3.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,195 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:91,209,494–106,752,694, 294 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr8:108,871,128–122,733,804, 112 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr8:123,157,729–124,728,473, 48 genes, copy number 7 (within-gene range 3–7): AC068228.3, FAM83A, U3, AC068228.1, AC068228.2, FAM83A-AS1, MIR4663, C8orf76, ZHX1-C8orf76, UBA52P5, ZHX1, RNU6-628P, AC018992.1, ATAD2, RNU6-875P, MIR548AA1, MIR548D1, DUTP2, IMPDH1P6, NTAQ1, U4, FBXO32, AC090193.1, RN7SKP155, AC135166.1, KLHL38, ANXA13, FAM91A1, FER1L6, AC090753.1, FER1L6-AS1, AC100871.2, FER1L6-AS2, AC100871.1, ARF1P3, AC090921.1, RNU6-756P, AC090192.2, AC090192.1, TMEM65, TRMT12, RNF139-AS1, RNF139, TATDN1, AC090198.1, MIR6844, NDUFB9, MTSS1.
- chr8:125,859,721–126,292,788, 1 gene, copy number 7 (within-gene range 3–7): LINC00861.
- chr8:125,951,861–133,814,537, 106 genes, copy number 7 (broad region; genes not listed).
- chr12:66,767–1,495,933, 29 genes, copy number 11–15 (within-gene range 4–15): IQSEC3, AC026369.3, AC026369.1, AC026369.2, AC007406.3, SLC6A12, AC007406.1, SLC6A12-AS1, SLC6A13, AC007406.2, AC007406.4, KDM5A, CCDC77, B4GALNT3, NINJ2, AC006205.2, RNU7-103P, AC006205.1, NINJ2-AS1, LINC02455, WNK1, RNU4ATAC16P, AC004765.1, RAD52, AC004803.1, ERC1, HTR1DP1, AC004672.1, AC004672.2.
- chr12:3,296,202–3,366,122, 1 gene, copy number 13 (within-gene range 3–13): AC005865.1.
- chr12:3,318,718–4,615,302, 26 genes, copy number 13–17 (within-gene range 3–17): LINC02827, LINC02417, PRMT8, AC005908.2, AC005908.1, THCAT155, CRACR2A, AC005831.1, RNU6-174P, AC006207.1, PARP11, OTUD4P1, PARP11-AS1, AC084375.1, HSPA8P5, AC007207.1, CCND2-AS1, CCND2, AC008012.1, TIGAR, AC006122.1, FGF23, FGF6, C12orf4, RAD51AP1, DYRK4.
- chr13:76,887,551–114,337,626, 486 genes, copy number 9 (broad region; genes not listed).
- chr22:22,910,574–23,907,068, 57 genes, copy number 11: IGLJ4, IGLC4, IGLJ5, IGLC5, IGLJ6, IGLC6, IGLJ7, IGLC7, AC245054.2, AC245054.1, RSPH14, GNAZ, Metazoa_SRP, U7, RAB36, BCR, BCRP8, RN7SL263P, FBXW4P1, AP000343.1, LINC02556, CES5AP1, ZDHHC8P1, AP000344.2, LINC01659, AP000344.1, FAM230I, AP000345.3, LINC02557, PCAT14, AP000345.1, IGLL1, AP000345.2, AP000346.4, DRICH1, AP000346.3, AP000346.1, GUSBP11, AP000346.2, ASLP1, AP000347.1, RGL4, ZNF70, VPREB3, C22orf15, CHCHD10, MMP11, SMARCB1, DERL3, AP000350.5, SLC2A11, AP000350.4, AP000350.8, RN7SL268P, MIF, MIF-AS1, AP000350.6.
- chr22:24,952,730–26,031,045, 35 genes, copy number 11 (within-gene range 5–11): KIAA1671, AL022323.2, AL022323.4, AL022323.1, AL022323.3, KIAA1671-AS1, Z99916.2, CRYBB3, Z99916.1, CRYBB2, Z99916.3, AL022332.1, AL022324.4, AL022332.2, IGLL3P, AL022324.1, AL022324.2, LRP5L, AL022324.3, AL008721.1, IGLVIVOR22-1, CRYBB2P1, MIR6817, AL008721.2, AL022329.1, GRK3, AL022329.2, YES1P1, RNA5SP494, MYO18B, AL022329.3, MYO18B-AS1, Z98949.2, RN7SKP169, Z98949.1.

Autosomal genes at a single copy (total copy number 1): 45. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
